Somatic mutation profile of tumor specimen TCGA-DM-A1DA-01A (aliquot TCGA-DM-A1DA-01A-11D-A152-10) from TCGA case TCGA-DM-A1DA, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.6 years (26,169 days).
Specimen TCGA-DM-A1DA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a758078c-0d19-4675-b06e-d0b4f16bf233.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1DA-10A (Blood Derived Normal), aliquot TCGA-DM-A1DA-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c43c592d-454b-4b02-8a6c-9dc584297497

The open-access MAF lists 305 somatic variants for this specimen: 238 protein-altering or splice-affecting, 60 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 207, Silent 60, Nonsense Mutation 13, Splice Site 9, Frame Shift Del 5, Intron 2, RNA 2, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3146G>A p.W1049* | Nonsense Mutation (SNP) | VAF 94/196 reads (48%) | catalogued as rs876658667, CM023009, COSV57322894, COSV99969466; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 61/142 reads (43%) | hotspot (GDC flag); catalogued as CM106374, COSV57326063, COSV57397024; called by muse, mutect2, varscan2
- ERBB4 | c.3005A>C p.K1002T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV61479977, COSV61490260; called by muse, mutect2, varscan2
- MAP2K4 | c.1041-2A>G p.X347_splice | Splice Site (SNP) | VAF 124/150 reads (83%) | hotspot (GDC flag); catalogued as COSV100796476, COSV62256207; called by muse, mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 105/121 reads (87%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 80/154 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 98/110 reads (89%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 265/320 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs374064269, COSV60622681; called by muse, mutect2, varscan2
- ACTRT1 | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64419128; called by muse, mutect2, varscan2
- ADAM12 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 59/87 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64104379; called by muse, mutect2, varscan2
- ADAM7 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 72/257 reads (28%) | catalogued as COSV51537440; called by muse, mutect2, varscan2
- ADGRG4 | c.3151G>A p.V1051I | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.157); catalogued as COSV99795834; called by muse, mutect2
- AEBP1 | c.3118G>A p.A1040T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs771161753, COSV99788872; called by muse, mutect2, varscan2
- AGGF1 | c.2042dup p.N681Kfs*11 | Frame Shift Ins (INS) | VAF 64/167 reads (38%) | catalogued as rs761190994; called by mutect2, varscan2
- AJM1 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777526568, COSV56032333; called by muse, mutect2, varscan2
- AKAP11 | c.1583T>C p.F528S | Missense Mutation (SNP) | VAF 196/428 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.086); catalogued as COSV50294607; called by muse, mutect2, varscan2
- AL645922.1 | c.1443G>C p.E481D | Missense Mutation (SNP) | VAF 142/156 reads (91%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV54960024; called by muse, mutect2, varscan2
- ALX3 | c.597C>A p.V199= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as COSV63928689; called by muse, mutect2, varscan2
- ANK2 | c.11859G>C p.E3953D | Missense Mutation (SNP) | VAF 145/158 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52153510; called by muse, mutect2, varscan2
- ANKEF1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65692161, COSV65692420; called by muse, mutect2, varscan2
- AP002748.5 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV100568003; called by muse, mutect2, varscan2
- APLF | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 176/280 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV58143737; called by muse, mutect2, varscan2
- APOL5 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.783); catalogued as rs1259239788, COSV50766548; called by muse, mutect2, varscan2
- ARC | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV63078280; called by muse, mutect2, varscan2
- ARHGAP4 | c.2231A>G p.D744G | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as COSV61685982; called by muse, mutect2, varscan2
- ARPP21 | c.1027G>T p.G343W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51794763; called by muse, mutect2, varscan2
- ARSL | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 118/275 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.168); catalogued as rs1456537486, COSV66965041; called by muse, mutect2, varscan2
- ASTN2 | c.2354C>A p.T785N (on ENST00000313400 / NM_001365069.1; = p.T734N on NM_014010.5) | Missense Mutation (SNP) | VAF 98/144 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs1438412104, COSV57765193; called by muse, mutect2, varscan2
- ATG16L1 | c.686A>G p.K229R | Missense Mutation (SNP) | VAF 177/525 reads (34%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.993); catalogued as rs1456464509, COSV61464955; called by muse, mutect2, varscan2
- BANF2 | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99856503; called by muse, mutect2, varscan2
- BARHL1 | c.177G>T p.L59F | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as COSV55037321; called by muse, mutect2, varscan2
- BCAS3 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV66771652; called by muse, mutect2, varscan2
- BCORL1 | c.2977C>T p.H993Y | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1345386158, COSV54392889, COSV99500396; called by muse, mutect2, varscan2
- BEND5 | c.1257T>A p.N419K | Missense Mutation (SNP) | VAF 138/286 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.932); catalogued as COSV65716822; called by muse, mutect2, varscan2
- BMPR1B | c.246+1G>T p.X82_splice | Splice Site (SNP) | VAF 247/282 reads (88%) | catalogued as COSV52776017; called by muse, mutect2, varscan2
- BRAF | c.1862A>T p.N621I (on ENST00000288602 / NM_001374244.1; = p.N581I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV56058108, COSV56106422, COSV56110832; called by muse, mutect2, varscan2
- C18orf54 | c.976-1G>A p.X326_splice | Splice Site (SNP) | VAF 178/207 reads (86%) | catalogued as rs753088233, COSV100266637, COSV55617672; called by muse, mutect2, varscan2
- C20orf27 | c.137A>G p.E46G (on ENST00000379772 / NM_001258429.2; = p.E71G on NM_001039140.3) | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV53923490; called by muse, mutect2, varscan2
- C22orf31 | c.286T>A p.F96I | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV53310325; called by muse, mutect2, varscan2
- C2orf78 | c.1858A>T p.K620* | Nonsense Mutation (SNP) | VAF 74/304 reads (24%) | catalogued as COSV68516985; called by muse, mutect2, varscan2
- C5 | c.2941G>T p.G981* | Nonsense Mutation (SNP) | VAF 76/131 reads (58%) | catalogued as COSV56325758; called by muse, mutect2, varscan2
- C7orf31 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99384018; called by muse, mutect2, varscan2
- CADM1 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV59006654; called by muse, mutect2, varscan2
- CATSPERB | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99831407; called by muse, mutect2, varscan2
- CCDC120 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.553); catalogued as rs990990503, COSV64480804; called by muse, mutect2, varscan2
- CCDC142 | c.1718C>A p.A573D (on ENST00000393965 / NM_001365575.2; = p.A566D on NM_032779.4) | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV50688439; called by muse, mutect2, varscan2
- CDC26 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 24/149 reads (16%) | catalogued as COSV65252455, COSV65253074; called by muse, mutect2, varscan2
- CDC73 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV66466050; called by muse, mutect2, varscan2
- CDHR2 | c.3143G>T p.R1048L | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV56136608, COSV99991169; called by muse, mutect2, varscan2
- CHRND | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51317864; called by muse, mutect2, varscan2
- CHST9 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 130/218 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV52434844, COSV99410344; called by muse, varscan2
- CLUH | c.1448C>T p.T483M (on ENST00000435359; = p.T521M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/59 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs950000630, COSV70927639; called by muse, mutect2, varscan2
- COL11A2 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 99/105 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV100554175; called by muse, mutect2, varscan2
- COL4A4 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV61630849; called by muse, mutect2, varscan2
- COL5A3 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 199/214 reads (93%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53408505; called by muse, mutect2, varscan2
- COL6A6 | c.5221C>T p.R1741C | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs367687833, COSV62029887; called by muse, mutect2, varscan2
- CSF3R | c.1983T>A p.S661R | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV58965188; called by muse, mutect2, varscan2
- CSMD3 | c.9883G>T p.G3295C (on ENST00000297405 / NM_001363185.1; = p.G3126C on NM_052900.3) | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837583; called by muse, mutect2, varscan2
- CTTNBP2 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748451490, COSV50393292; called by muse, mutect2, varscan2
- CUL9 | c.6716G>C p.C2239S | Missense Mutation (SNP) | VAF 61/66 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52727011; called by muse, mutect2, varscan2
- CYLC1 | c.1208T>G p.I403S | Missense Mutation (SNP) | VAF 160/354 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV61411064; called by muse, mutect2, varscan2
- CYP11B1 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs139569725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCLK1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 231/497 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs777971990, COSV55179492; called by muse, mutect2, varscan2
- DHRS1 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55383675; called by muse, mutect2, varscan2
- DISP3 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.543); catalogued as rs1204979180, COSV53824274; called by muse, mutect2, varscan2
- DNAH11 | c.6859C>T p.R2287C | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771419966, COSV60994909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRC1 | c.1826A>G p.E609G | Missense Mutation (SNP) | VAF 138/215 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55499657; called by muse, mutect2, varscan2
- DSCAML1 | c.5867G>A p.S1956N (on ENST00000321322; = p.S1896N on NM_020693.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as COSV100356316; called by muse, mutect2
- DSCAML1 | c.5459G>A p.R1820H (on ENST00000321322; = p.R1760H on NM_020693.4) | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.961); catalogued as rs758832848, COSV58386824; called by muse, mutect2, varscan2
- DYSF | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs1301200599, COSV50285713; called by muse, mutect2, varscan2
- EPHA2 | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760459530, COSV100626182, COSV64452565; called by muse, mutect2, varscan2
- EPHA7 | c.1852A>G p.N618D | Missense Mutation (SNP) | VAF 85/322 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.445); catalogued as COSV65180178; called by muse, mutect2, varscan2
- ESYT1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV57272202; called by muse, mutect2, varscan2
- F2 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs752361229, COSV61314857; called by muse, mutect2, varscan2
- FAM102A | c.931T>C p.S311P (on ENST00000373095 / NM_001035254.3; = p.S169P on NM_203305.2) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55947591; called by muse, mutect2, varscan2
- FAM199X | c.223A>C p.S75R | Missense Mutation (SNP) | VAF 157/372 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV72419825; called by muse, mutect2, varscan2
- FARP2 | c.2505-1G>C p.X835_splice | Splice Site (SNP) | VAF 36/109 reads (33%) | catalogued as COSV99884831; called by muse, mutect2, varscan2
- FAT2 | c.11140G>A p.V3714M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV55816594; called by muse, mutect2, varscan2
- FAT3 | c.5319A>T p.Q1773H | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV53093064; called by muse, mutect2, varscan2
- FRMPD1 | c.4322G>A p.G1441E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV66699747; called by muse, mutect2, varscan2
- FRY | c.7075G>T p.A2359S | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV66567570; called by muse, mutect2, varscan2
- G2E3 | c.528+1G>A p.X176_splice | Splice Site (SNP) | VAF 70/161 reads (43%) | catalogued as COSV99249721; called by muse, mutect2, varscan2
- GAD1 | c.639-1G>T p.X213_splice | Splice Site (SNP) | VAF 139/368 reads (38%) | catalogued as COSV100713851; called by muse, mutect2, varscan2
- GIMAP1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV56187624; called by muse, mutect2, varscan2
- GPR142 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 83/90 reads (92%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs552563622, COSV59519019; called by muse, mutect2, varscan2
- GPR149 | c.1013T>C p.F338S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV67666615; called by muse, mutect2, varscan2
- GPR26 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 197/220 reads (90%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as rs1174980270, COSV52933378; called by muse, mutect2, varscan2
- GRIN3A | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV62452146; called by muse, mutect2, varscan2
- HABP2 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63636260; called by muse, mutect2, varscan2
- HAUS3 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 205/226 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV54722284; called by muse, varscan2
- HAVCR2 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1488560271, COSV100324823; called by muse, mutect2, varscan2
- HECW1 | c.460+1G>A p.X154_splice | Splice Site (SNP) | VAF 66/237 reads (28%) | catalogued as COSV67823008; called by muse, mutect2, varscan2
- HMOX1 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV53339411; called by muse, mutect2, varscan2
- HNRNPR | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.538); catalogued as COSV56420798; called by muse, mutect2, varscan2
- HUWE1 | c.12064C>T p.R4022C | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV53340071; called by muse, mutect2, varscan2
- IFNA5 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV52386715, COSV52387456; called by muse, mutect2, varscan2
- IFT81 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs1435114143, COSV54361589; called by muse, mutect2, varscan2
- IGSF9 | c.2636G>A p.R879H (on ENST00000368094 / NM_001135050.2; = p.R863H on NM_020789.4) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs552997339, COSV57421913; called by muse, mutect2, varscan2
- IRF6 | c.916G>T p.V306F | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV65418679, COSV65419039; called by muse, mutect2, varscan2
- IRGC | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.52); PolyPhen benign (0.035); catalogued as rs756387844, COSV54983484, COSV99746408; called by muse, mutect2, varscan2
- ITGAL | c.1638G>C p.E546D | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63321125; called by muse, mutect2, varscan2
- KCNA1 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 75/86 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778463081, COSV66836531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCND2 | c.844A>C p.N282H | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58574530; called by muse, mutect2, varscan2
- KCTD16 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs773343153, COSV72577989; called by muse, mutect2, varscan2
- KDM5B | c.3256C>G p.L1086V | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52506208; called by muse, mutect2, varscan2
- KEL | c.1611G>C p.W537C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV62334138, COSV62335809; called by muse, mutect2, varscan2
- KHDRBS2 | c.960A>C p.E320D | Missense Mutation (SNP) | VAF 168/189 reads (89%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.99); catalogued as rs542084033, COSV55439851, COSV55449017, COSV99836744; called by muse, mutect2, varscan2
- KIF1B | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55806096; called by muse, mutect2, varscan2
- KIF26A | c.4447G>A p.G1483S | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs775132075, COSV59465587; called by muse, mutect2, varscan2
- KLHL34 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV65279031; called by muse, mutect2, varscan2
- KRT32 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 66/77 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs141728288; called by muse, mutect2, varscan2
- KRT34 | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 123/135 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV67449539; called by muse, mutect2, varscan2
- LATS2 | c.2023G>T p.G675W | Missense Mutation (SNP) | VAF 126/232 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66874351; called by muse, mutect2, varscan2
- LCP2 | c.1462G>C p.G488R | Missense Mutation (SNP) | VAF 148/296 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50448183; called by muse, mutect2, varscan2
- LOXL1 | c.1711A>C p.I571L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV56093861; called by muse, mutect2, varscan2
- LOXL4 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53255919; called by muse, mutect2, varscan2
- LRIT2 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1295110262, COSV60560894, COSV60561319; called by muse, mutect2, varscan2
- MACROH2A2 | c.824A>T p.H275L | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100325737; called by muse, mutect2
- MAGEC2 | c.828A>C p.K276N | Missense Mutation (SNP) | VAF 100/185 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV55997644, COSV99909877; called by muse, mutect2, varscan2
- MAGED2 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 133/241 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1388401939, COSV54497388, COSV54499194; called by muse, mutect2, varscan2
- MAP1B | c.5843G>A p.R1948Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139240427; called by muse, mutect2
- MAP3K12 | c.1772C>A p.P591H | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.431); catalogued as COSV57232158; called by muse, mutect2, varscan2
- MEOX1 | c.122C>G p.T41S | Missense Mutation (SNP) | VAF 144/156 reads (92%) | SIFT tolerated (0.95); PolyPhen benign (0.014); catalogued as rs1482401910, COSV59355714; called by muse, mutect2, varscan2
- MET | c.1721C>G p.P574R | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59259252; called by muse, mutect2, varscan2
- MIB2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.108); catalogued as rs944283862, COSV61755409; called by muse, mutect2, varscan2
- MIDN | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99960258; called by muse, mutect2, varscan2
- MON2 | c.3109C>G p.R1037G | Missense Mutation (SNP) | VAF 201/222 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99742852; called by muse, mutect2, varscan2
- MPP2 | c.1663G>A p.E555K (on ENST00000461854 / NM_001278372.2; = p.E531K on NM_005374.5) | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373923258, COSV52234620; called by muse, mutect2, varscan2
- MTCL1 | c.4904C>T p.T1635M (on ENST00000306329 / NM_001378206.1; = p.T1316M on NM_015210.4) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs375774425, COSV60403076; called by muse, mutect2, varscan2
- MTUS2 | c.1950G>T p.R650S | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70915428, COSV70918212; called by muse, mutect2, varscan2
- MUC16 | c.34027G>T p.E11343* | Nonsense Mutation (SNP) | VAF 128/147 reads (87%) | catalogued as COSV67455859; called by muse, mutect2, varscan2
- MUSK | c.2506C>T p.R836C | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769657813, COSV51882214; called by muse, mutect2, varscan2
- NEB | c.16073T>A p.L5358Q | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs370211010; called by muse, mutect2, varscan2
- NEUROG3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766165230, COSV54342517; called by muse, mutect2, varscan2
- NINL | c.555C>G p.S185R | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as rs532756641, COSV54000477; called by muse, mutect2, varscan2
- NME9 | c.464C>T p.S155L (on ENST00000333911 / NM_001349024.2; = p.S94L on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/265 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV58617477; called by muse, mutect2, varscan2
- NPBWR1 | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100488240; called by muse, mutect2, varscan2
- NRROS | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs753726007, COSV60745247; called by muse, mutect2, varscan2
- NUP188 | c.3429+1G>A p.X1143_splice | Splice Site (SNP) | VAF 22/100 reads (22%) | catalogued as COSV65361118; called by muse, mutect2, varscan2
- NXT1 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 130/222 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54782829; called by muse, mutect2
- OPTN | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 154/250 reads (62%) | catalogued as COSV53810282; called by muse, mutect2, varscan2
- OR10AG1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.19); catalogued as rs77704611, COSV56632008; called by muse, mutect2, varscan2
- OR11H12 | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 152/524 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1196407205, COSV101612504; called by muse, varscan2
- PAX5 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1385943435, COSV63906247; called by muse, mutect2, varscan2
- PCDHA1 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV65373779; called by muse, mutect2, varscan2
- PCDHGA12 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.087); catalogued as COSV52747320; called by muse, mutect2, varscan2
- PCDHGC5 | c.965C>G p.A322G | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99340705; called by muse, mutect2, varscan2
- PDCD1LG2 | c.115A>T p.T39S | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV101173100; called by muse, mutect2, varscan2
- PDZD2 | c.5761C>A p.Q1921K | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV56854689; called by muse, mutect2, varscan2
- PENK | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV59240641; called by muse, mutect2, varscan2
- PER2 | c.2914G>T p.A972S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54522394; called by muse, mutect2, varscan2
- PIK3R6 | c.1300T>A p.Y434N | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100266605; called by muse, mutect2, varscan2
- PLD5 | c.1316G>A p.R439H (on ENST00000442594; = p.R377H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs747669178, COSV59139492; called by muse, mutect2, varscan2
- PLPPR1 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66451910, COSV66457814; called by muse, mutect2, varscan2
- POMT2 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs746579730, COSV55070416; called by muse, mutect2, varscan2
- PORCN | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs986541030, COSV58225807; called by muse, mutect2, varscan2
- PRADC1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs779609316, COSV57820056; called by muse, mutect2, varscan2
- PRDM7 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 153/167 reads (92%) | catalogued as rs371622874; called by muse, mutect2, varscan2
- PRKCG | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 65/70 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs751774653, COSV54725976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSD2 | c.1662G>T p.Q554H | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.262); catalogued as COSV51198055; called by muse, mutect2, varscan2
- PYDC2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV72921291; called by muse, mutect2, varscan2
- PYGO2 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 56/100 reads (56%) | catalogued as COSV63756764; called by muse, mutect2, varscan2
- RAB34 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV56385797; called by muse, mutect2, varscan2
- RAE1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 78/123 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64797991; called by muse, mutect2, varscan2
- RAP1GAP | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1231458529, COSV51570766; called by muse, mutect2, varscan2
- RIMBP3 | c.2449G>A p.V817M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs1351222148; called by mutect2, varscan2
- RNF113A | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV101007069; called by muse, mutect2, varscan2
- RNF19B | c.1346G>A p.S449N | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99331526; called by muse, mutect2, varscan2
- ROBO2 | c.4052C>A p.A1351E | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV59904202; called by muse, mutect2, varscan2
- RSPH3 | c.1334C>A p.T445N (on ENST00000252655; = p.T303N on NM_031924.8) | Missense Mutation (SNP) | VAF 88/93 reads (95%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV51921846; called by muse, mutect2, varscan2
- SACS | c.3863C>T p.A1288V | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV66537570; called by muse, mutect2, varscan2
- SALL4 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV53851098; called by muse, mutect2, varscan2
- SAMD12 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 149/272 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59047563; called by muse, mutect2, varscan2
- SCEL | c.1097G>A p.G366E (on ENST00000349847 / NM_144777.3; = p.G346E on NM_003843.4) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV62993202; called by muse, mutect2, varscan2
- SCN7A | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV69270343; called by muse, mutect2, varscan2
- SCN8A | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1049676859, COSV61978805; called by muse, mutect2, varscan2
- SEMA3C | c.1555A>G p.T519A | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54843988; called by muse, mutect2, varscan2
- SEMA5B | c.2861C>T p.T954M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1560277290, COSV52094376; called by muse, mutect2, varscan2
- SETD3 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 54/116 reads (47%) | catalogued as COSV59283545; called by muse, mutect2, varscan2
- SGSM1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68509509; called by muse, mutect2, varscan2
- SLC17A6 | c.633G>T p.R211S | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs949352338, COSV54134860; called by muse, mutect2, varscan2
- SLC25A15 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV58556840; called by muse, mutect2, varscan2
- SLC25A30 | c.83T>A p.L28* | Nonsense Mutation (SNP) | VAF 106/241 reads (44%) | catalogued as COSV60433524; called by muse, mutect2, varscan2
- SLC4A1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 96/105 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs745839527, COSV52259229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A10 | c.1402C>A p.H468N (on ENST00000446997 / NM_001354461.2; = p.H438N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs575906578, COSV99764610; called by muse, mutect2, varscan2
- SLC4A2 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776189342, COSV52539595; called by muse, mutect2, varscan2
- SLC52A1 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54692625; called by muse, mutect2, varscan2
- SLC8B1 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV52527042; called by muse, mutect2, varscan2
- SMAD3 | c.1181G>T p.C394F | Missense Mutation (SNP) | VAF 72/82 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59283739; called by muse, mutect2, varscan2
- SMARCA2 | c.3529G>A p.V1177M | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV61806106; called by muse, mutect2, varscan2
- SNTG2 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100423233; called by muse, mutect2, varscan2
- SNX15 | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as COSV57246360; called by muse, mutect2, varscan2
- SPEG | c.8440C>A p.P2814T | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100404798; called by muse, mutect2, varscan2
- STAT4 | c.19del p.V7Sfs*4 | Frame Shift Del (DEL) | VAF 89/189 reads (47%) | catalogued as COSV61828922; called by mutect2, pindel, varscan2
- STK32B | c.142A>T p.M48L | Missense Mutation (SNP) | VAF 72/78 reads (92%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV51479484; called by muse, mutect2, varscan2
- SULT1C3 | c.155C>A p.A52E | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61252682; called by muse, mutect2, varscan2
- SUSD3 | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.011); catalogued as COSV64937131; called by muse, mutect2, varscan2
- TCOF1 | c.1546C>A p.P516T (on ENST00000377797 / NM_001135243.1; = p.P439T on NM_000356.4) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); catalogued as COSV60347175; called by muse, mutect2, varscan2
- TENM3 | c.7822C>T p.R2608C | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69303337; called by muse, mutect2, varscan2
- TENM4 | c.2218G>A p.V740I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs370272010; called by muse, mutect2, varscan2
- THRA | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV52841754; called by muse, mutect2, varscan2
- TJP3 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs371222022; called by muse, mutect2, varscan2
- TLX2 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.432); catalogued as COSV52045536; called by muse, mutect2, varscan2
- TMEM135 | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1416661392, COSV59698248; called by muse, varscan2
- TNFRSF4 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs754604681, COSV64878865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1811C>G p.P604R | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV64100525; called by muse, mutect2, varscan2
- TNS1 | c.3230C>A p.S1077Y | Missense Mutation (SNP) | VAF 75/117 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50695569; called by muse, mutect2, varscan2
- TOGARAM2 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs543434094, COSV65422662; called by muse, mutect2, varscan2
- TOGARAM2 | c.1229C>A p.S410Y | Missense Mutation (SNP) | VAF 134/210 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65420557; called by muse, mutect2
- TREH | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs782349165, COSV99874553; called by muse, mutect2, varscan2
- TSHZ3 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 118/136 reads (87%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs200738522, COSV53667763, COSV53669143, COSV53674591; called by muse, mutect2, varscan2
- TTN | c.6950G>A p.R2317H (on ENST00000591111; = p.R2271H on NM_003319.4) | Missense Mutation (SNP) | VAF 120/328 reads (37%) | PolyPhen probably damaging (0.998); catalogued as rs764882950, COSV100611973, COSV59964339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUB | c.1237C>T p.R413C (on ENST00000299506 / NM_177972.3; = p.R468C on NM_003320.4) | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs146835743, COSV55107311; called by muse, mutect2, varscan2
- UNC13C | c.3985T>G p.L1329V | Missense Mutation (SNP) | VAF 101/103 reads (98%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52842755, COSV52856856; called by muse, mutect2, varscan2
- USP44 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 163/175 reads (93%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs1461079841, COSV51562895; called by muse, mutect2, varscan2
- VCAN | c.7507A>G p.T2503A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV54101664; called by muse, mutect2, varscan2
- VIL1 | c.2024C>A p.A675E | Missense Mutation (SNP) | VAF 90/135 reads (67%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.555); catalogued as COSV50286479; called by muse, mutect2, varscan2
- VIPR2 | c.789G>C p.R263S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765248907, COSV51104653; called by muse, mutect2, varscan2
- VRTN | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs1191327811, COSV56442808; called by muse, mutect2, varscan2
- WDR49 | c.252+1G>A p.X84_splice (on ENST00000308378 / NM_001366158.1; = p.X425_splice on NM_001348951.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 106/232 reads (46%) | catalogued as COSV57705492; called by muse, mutect2, varscan2
- XDH | c.2686C>T p.R896W | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765576781, COSV65147792; called by muse, mutect2, varscan2
- XPO7 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs758800640, COSV53013034; called by muse, mutect2, varscan2
- ZBTB10 | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV66946843, COSV66948791; called by muse, mutect2, varscan2
- ZCCHC12 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 79/199 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59571226; called by mutect2, varscan2
- ZIC3 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.524); catalogued as COSV54973188; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58742398; called by muse, mutect2, varscan2
- ZNF43 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 149/162 reads (92%) | SIFT tolerated (0.52); PolyPhen benign (0.264); catalogued as COSV61683433; called by muse, mutect2, varscan2
- ZNF623 | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV101513568; called by muse, mutect2, varscan2
- ZNF707 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1225878440, COSV62311175; called by muse, mutect2, varscan2
- ZNF746 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV61406896; called by muse, mutect2, varscan2
- ACVR2A | c.946_954del p.P316_I318del | In Frame Del (DEL) | VAF 53/86 reads (62%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1291G>C p.G431R | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1D | c.2522_2525del p.A841Dfs*10 (on ENST00000350061 / NM_001128840.3; = p.A861Dfs*10 on NM_000720.4) | Frame Shift Del (DEL) | VAF 15/24 reads (63%) | called by mutect2, pindel, varscan2
- GDF10 | c.851C>A p.A284E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- GRIK4 | c.1437_1453del p.T481Rfs*6 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- HERC2 | c.160del p.Q54Rfs*23 | Frame Shift Del (DEL) | VAF 266/298 reads (89%) | called by mutect2, varscan2
- MYH9 | c.2819_2821dup p.K940dup | In Frame Ins (INS) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- PTEN | c.484_485del p.D162Qfs*17 | Frame Shift Del (DEL) | VAF 166/270 reads (61%) | called by pindel, varscan2
- ADAM18 | c.330A>T p.I110= | Silent (SNP) | VAF 41/146 reads (28%) | catalogued as COSV55845556; called by muse, mutect2, varscan2
- ANKS6 | c.1839T>G p.V613= | Silent (SNP) | VAF 58/96 reads (60%) | catalogued as COSV62049771; called by muse, mutect2, varscan2
- ARMH4 | c.1335T>G p.S445= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV50762911; called by muse, mutect2, varscan2
- BARX1 | c.507G>A p.T169= | Silent (SNP) | VAF 97/144 reads (67%) | catalogued as rs765029144, COSV54158833; called by muse, mutect2, varscan2
- BNC1 | c.246G>A p.V82= | Silent (SNP) | VAF 78/85 reads (92%) | catalogued as rs749950118, COSV61757004; called by muse, mutect2, varscan2
- BSN | c.7560G>A p.G2520= | Silent (SNP) | VAF 39/48 reads (81%) | catalogued as rs759406626, COSV56515283; called by muse, mutect2, varscan2
- CCL21 | c.15G>A p.L5= | Silent (SNP) | VAF 62/90 reads (69%) | catalogued as COSV52398726; called by muse, mutect2, varscan2
- CDH11 | c.1605C>A p.I535= | Silent (SNP) | VAF 129/158 reads (82%) | catalogued as COSV51756653, COSV99216774; called by muse, varscan2
- CDH18 | c.1506T>A p.P502= | Silent (SNP) | VAF 70/124 reads (56%) | catalogued as COSV56911889; called by muse, mutect2, varscan2
- CELF4 | c.63C>T p.N21= | Silent (SNP) | VAF 92/106 reads (87%) | catalogued as COSV58450185; called by muse, mutect2, varscan2
- CHST1 | c.828C>T p.C276= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV57321601; called by muse, mutect2, varscan2
- CMYA5 | c.11889C>A p.S3963= | Silent (SNP) | VAF 57/110 reads (52%) | catalogued as COSV69745348, COSV69746091; called by muse, mutect2, varscan2
- CTNND1 | c.1281A>G p.G427= | Silent (SNP) | VAF 56/120 reads (47%) | catalogued as rs1234394884, COSV100650157; called by muse, mutect2, varscan2
- DCP2 | c.27C>T p.P9= | Silent (SNP) | VAF 65/127 reads (51%) | catalogued as rs769592289, COSV101203921; called by muse, mutect2, varscan2
- DHX34 | c.1362C>T p.F454= | Silent (SNP) | VAF 66/70 reads (94%) | catalogued as rs760201365, COSV60894857; called by muse, mutect2, varscan2
- EMILIN1 | c.1041C>A p.R347= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV53154018; called by muse, mutect2, varscan2
- EXTL3 | c.1308C>T p.P436= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs144597012; called by muse, mutect2, varscan2
- FADS2 | c.219C>T p.R73= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs545952540, COSV53897700; called by muse, mutect2, varscan2
- FLNC | c.4008C>T p.P1336= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV57953251; called by muse, mutect2, varscan2
- GDF9 | c.1326G>A p.E442= | Silent (SNP) | VAF 76/204 reads (37%) | catalogued as COSV51526035; called by muse, mutect2, varscan2
- GLIPR1L1 | c.549C>T p.Y183= | Silent (SNP) | VAF 190/209 reads (91%) | catalogued as rs755736970, COSV56881178; called by muse, mutect2, varscan2
- GPC6 | c.1608C>T p.H536= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV65505231; called by muse, mutect2, varscan2
- GSTA5 | c.21C>T p.L7= | Silent (SNP) | VAF 167/183 reads (91%) | catalogued as COSV52861832; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.258A>G p.R86= | Silent (SNP) | VAF 141/455 reads (31%) | catalogued as rs551784969; called by muse, mutect2, varscan2
- IGHV6-1 | c.105G>A p.S35= | Silent (SNP) | VAF 61/139 reads (44%) | catalogued as rs782819311; called by muse, mutect2, varscan2
- INSL6 | c.471C>A p.T157= | Silent (SNP) | VAF 221/398 reads (56%) | catalogued as COSV67562769; called by muse, mutect2, varscan2
- JRK | c.222G>A p.A74= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs781865813, COSV70629686; called by muse, mutect2, varscan2
- KCNK13 | c.744C>T p.N248= | Silent (SNP) | VAF 84/187 reads (45%) | catalogued as rs574638305, COSV56411938; called by muse, mutect2, varscan2
- KIF3C | c.1272C>A p.G424= | Silent (SNP) | VAF 79/139 reads (57%) | catalogued as COSV53098576; called by muse, mutect2, varscan2
- LRRC4 | c.390G>T p.L130= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs764268218, COSV50813519; called by muse, mutect2, varscan2
- MACROH2A2 | c.822C>A p.I274= | Silent (SNP) | VAF 60/95 reads (63%) | catalogued as rs751285162, COSV57158969; called by muse, mutect2
- MAGEA6 | c.591C>G p.P197= | Silent (SNP) | VAF 160/444 reads (36%) | catalogued as COSV61448824; called by muse, mutect2, varscan2
- MAMDC4 | c.72C>A p.V24= | Silent (SNP) | VAF 80/132 reads (61%) | catalogued as COSV99915730; called by muse, mutect2, varscan2
- MGAM | c.3237G>A p.E1079= | Silent (SNP) | VAF 50/203 reads (25%) | catalogued as COSV72074204; called by muse, mutect2, varscan2
- MUC16 | c.16536C>A p.P5512= | Silent (SNP) | VAF 309/342 reads (90%) | catalogued as COSV67445491; called by muse, mutect2, varscan2
- MYLK | c.4743C>T p.I1581= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs371814184; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- NFATC2 | c.2082C>T p.I694= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV65354353; called by muse, mutect2, varscan2
- NPHS1 | c.3573C>A p.P1191= | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as COSV62287084; called by muse, mutect2, varscan2
- OR10A6 | c.801A>C p.S267= | Silent (SNP) | VAF 96/232 reads (41%) | catalogued as COSV100564306; called by muse, mutect2, varscan2
- OR4N2 | c.111C>A p.I37= | Silent (SNP) | VAF 172/778 reads (22%) | catalogued as COSV100269992, COSV60050708; called by muse, mutect2, varscan2
- PCDHGA2 | c.2097G>A p.A699= | Silent (SNP) | VAF 116/224 reads (52%) | catalogued as rs142588721, COSV53921180; called by muse, mutect2, varscan2
- PEX16 | c.39G>A p.E13= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV53801398; called by muse, mutect2, varscan2
- PHIP | c.288A>G p.G96= | Silent (SNP) | VAF 134/150 reads (89%) | catalogued as COSV51502925; called by muse, mutect2, varscan2
- PIK3R4 | c.1827C>T p.G609= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV63239959; called by muse, mutect2, varscan2
- POTEH | c.306C>T p.C102= | Silent (SNP) | VAF 98/392 reads (25%) | catalogued as COSV100625168, COSV58881587; called by muse, mutect2, varscan2
- RIMS2 | c.4551A>G p.K1517= (on ENST00000666250 / NM_001348490.2; = p.K1088= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 57/218 reads (26%) | catalogued as COSV51654501, COSV51667566; called by muse, mutect2, varscan2
- SCARB2 | c.1335G>C p.L445= | Silent (SNP) | VAF 223/251 reads (89%) | catalogued as COSV53668237; called by muse, mutect2, varscan2
- SHROOM2 | c.4497G>A p.V1499= | Silent (SNP) | VAF 90/205 reads (44%) | catalogued as COSV101098779; called by muse, mutect2, varscan2
- SNTG2 | c.708G>A p.T236= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as rs202059053, COSV57967552; called by muse, varscan2
- SOGA3 | c.2604C>T p.H868= | Silent (SNP) | VAF 67/73 reads (92%) | catalogued as COSV64105915; called by muse, mutect2, varscan2
- SORCS3 | c.3474A>G p.Q1158= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV63806254; called by muse, mutect2, varscan2
- ST8SIA5 | c.837G>A p.P279= | Silent (SNP) | VAF 45/47 reads (96%) | catalogued as rs148495308; called by muse, mutect2, varscan2
- STX2 | c.273G>A p.K91= | Silent (SNP) | VAF 239/259 reads (92%) | catalogued as COSV55432671; called by muse, varscan2
- TNFSF14 | c.276C>A p.V92= | Silent (SNP) | VAF 24/24 reads (100%) | catalogued as COSV55590246, COSV55591569; called by muse, mutect2, varscan2
- TPTE | c.1656A>G p.*552= (on ENST00000618007 / NM_199261.4; = p.*534= on NM_199259.4) | Silent (SNP) | VAF 106/382 reads (28%) | called by muse, mutect2, varscan2
- TRPC7 | c.2283C>G p.G761= | Silent (SNP) | VAF 145/320 reads (45%) | catalogued as COSV61456037; called by muse, mutect2, varscan2
- TTN | c.19416G>A p.P6472= (on ENST00000591111; = p.P5545= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as rs368422028; ClinVar: likely benign; called by muse, mutect2, varscan2
- VWCE | c.1839C>T p.H613= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV57111554; called by muse, mutect2, varscan2
- WARS1 | c.1173G>T p.G391= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV59924919; called by muse, mutect2, varscan2
- ZBTB10 | c.2070T>C p.G690= (on ENST00000430430; = p.G666= on NM_023929.4) | Silent (SNP) | VAF 170/330 reads (52%) | catalogued as COSV66946850; called by muse, mutect2, varscan2
- AL133467.6 | n.39G>A | RNA (SNP) | VAF 55/102 reads (54%) | called by muse, mutect2
- EPSTI1 | chr13:42888453 C>A | 3'Flank (SNP) | VAF 146/317 reads (46%) | catalogued as COSV100553167, COSV58044698; called by muse, mutect2, varscan2
- HEXD | c.*6G>A | 3'UTR (SNP) | VAF 42/45 reads (93%) | catalogued as rs754807818, COSV60063389; called by muse, mutect2, varscan2
- KNOP1P1 | n.79G>T | RNA (SNP) | VAF 47/54 reads (87%) | called by muse, mutect2, varscan2
- MCF2L | c.368+2112G>A | Intron (SNP) | VAF 15/26 reads (58%) | catalogued as rs376704623, COSV100982703; called by muse, mutect2, varscan2
- MDFI | c.-1G>A | 5'UTR (SNP) | VAF 30/33 reads (91%) | catalogued as COSV100025694; called by muse, mutect2
- WNT4 | c.313+2341G>C | Intron (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
